Somatic mutation profile of tumor specimen TCGA-OR-A5JM-01A (aliquot TCGA-OR-A5JM-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JM, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 25.6 years (9,359 days).
Specimen TCGA-OR-A5JM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 047d40f9-d3fc-4acb-aeb8-c151791cbf00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JM-10B (Blood Derived Normal), aliquot TCGA-OR-A5JM-10B-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5c8a0a4-2593-435f-9638-3995bcfa7971

The open-access MAF lists 67 somatic variants for this specimen: 49 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 15, Frame Shift Del 6, In Frame Del 3, Intron 3, Splice Site 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133_135del p.S45del | In Frame Del (DEL) | VAF 44/143 reads (31%) | hotspot (GDC flag); catalogued as rs587776850; ClinVar: pathogenic / other; called by mutect2, pindel, varscan2
- APEX1 | c.847G>C p.D283H | Missense Mutation (SNP) | VAF 95/207 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1453612380, COSV51658199; called by muse, mutect2, varscan2
- FUT6 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 145/340 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs140726017; called by muse, mutect2, varscan2
- IZUMO2 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.421); catalogued as COSV53229360; called by muse, mutect2, varscan2
- KRT33A | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50377225; called by muse, mutect2, varscan2
- NELFE | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs542263058; called by muse, mutect2, varscan2
- NTN3 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs375026789; called by muse, mutect2, varscan2
- PARP1 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 64/287 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.285); catalogued as rs200485374; called by muse, mutect2, varscan2
- PIK3C2G | c.2674C>T p.H892Y (on ENST00000676171; = p.H851Y on NM_004570.5) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.18); catalogued as rs767773999, COSV104383783; called by muse, mutect2
- RBM41 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs775670658, COSV99179759; called by muse, mutect2, varscan2
- RRNAD1 | c.815_817del p.S272del | In Frame Del (DEL) | VAF 28/95 reads (29%) | catalogued as rs1379348872; called by mutect2, pindel, varscan2
- SERAC1 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.506); catalogued as rs372754952; called by muse, mutect2, varscan2
- SH3BP1 | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.812); catalogued as rs768349095; called by muse, mutect2, varscan2
- SUN1 | c.1886_1887del p.E629Gfs*18 (on ENST00000405266 / NM_001367651.1; = p.E509Gfs*18 on NM_025154.6 and 13 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 30/120 reads (25%) | catalogued as rs1562776172; called by pindel, varscan2
- ADGRA3 | c.2975_2976del p.F992Sfs*36 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | called by mutect2, pindel, varscan2
- AGBL2 | c.1231G>C p.A411P | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- ATM | c.1899-1_1902del p.X633_splice | Splice Site (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- CDH23 | c.9380G>A p.G3127E | Missense Mutation (SNP) | VAF 55/261 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDKN2A | c.89_104del p.A30Gfs*18 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- CEP162 | c.1368_1370del p.S458del | In Frame Del (DEL) | VAF 14/76 reads (18%) | called by pindel, varscan2
- COL5A2 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DENND2C | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ECI2 | c.1045A>G p.K349E (on ENST00000380118 / NM_206836.3; = p.K319E on NM_006117.2) | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FAM171B | c.1498A>G p.N500D | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR19 | c.295A>G p.T99A | Missense Mutation (SNP) | VAF 17/371 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- HSPA4 | c.316_317del p.M106Gfs*9 | Frame Shift Del (DEL) | VAF 23/92 reads (25%) | called by pindel, varscan2
- NECAP1 | c.274T>G p.F92V | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUFIP2 | c.421G>C p.A141P | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR5K3 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PAK3 | c.476-1G>A p.X159_splice (on ENST00000262836 / NM_001324328.2; = p.X144_splice on NM_002578.5 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 33/105 reads (31%) | called by muse, mutect2, varscan2
- PCDH18 | c.3067T>C p.Y1023H | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- PCDHA3 | c.2024C>A p.A675E | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); called by muse, varscan2
- PEAR1 | c.1301G>A p.C434Y | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNMA8B | c.1141A>G p.K381E | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- QARS1 | c.1673G>C p.R558P | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHANK3 | c.2022dup p.K675Qfs*18 | Frame Shift Ins (INS) | VAF 35/110 reads (32%) | called by mutect2, pindel, varscan2
- SNRNP200 | c.655del p.E219Rfs*27 | Frame Shift Del (DEL) | VAF 27/165 reads (16%) | called by mutect2, pindel, varscan2
- STON2 | c.2134G>C p.V712L (on ENST00000649389 / NM_001366849.2; = p.V655L on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/210 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- TAAR9 | c.697A>T p.S233C | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- TCP10L3 | n.2619-1G>T | Splice Site (SNP) | VAF 56/1136 reads (5%) | called by muse, mutect2
- TMEM200A | c.653G>C p.S218T | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TMEM74 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TRIOBP | c.3854G>C p.R1285T | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- TSNAXIP1 | c.630C>G p.D210E | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- TTC31 | c.88A>C p.K30Q | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); called by muse, mutect2
- TUT7 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- URGCP | c.2722_2723del p.E908Kfs*18 (on ENST00000453200 / NM_001077663.3; = p.E899Kfs*18 on NM_017920.4) | Frame Shift Del (DEL) | VAF 47/169 reads (28%) | called by mutect2, pindel, varscan2
- ZDHHC6 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZNF23 | c.1297T>A p.S433T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.371); called by muse, varscan2
- ANKRD46 | c.387A>G p.E129= | Silent (SNP) | VAF 29/129 reads (22%) | called by muse, mutect2
- CACNA1E | c.6876G>A p.G2292= (on ENST00000367573 / NM_001205293.3; = p.G2249= on NM_000721.4) | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV100705174; called by muse, mutect2, varscan2
- CCDC14 | c.2676G>A p.A892= (on ENST00000488653; = p.A844= on NM_022757.5) | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as rs745716061, COSV59942977; called by muse, mutect2, varscan2
- EPHB4 | c.1395G>A p.L465= | Silent (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- MAP1S | c.2574C>T p.N858= | Silent (SNP) | VAF 33/122 reads (27%) | called by muse, mutect2, varscan2
- MAP3K15 | c.1722T>C p.F574= | Silent (SNP) | VAF 21/74 reads (28%) | called by muse, mutect2, varscan2
- OR5M11 | c.270C>A p.T90= | Silent (SNP) | VAF 40/142 reads (28%) | called by muse, mutect2, varscan2
- PLK2 | c.195G>C p.S65= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs1240257469, COSV99956273; called by muse, mutect2, varscan2
- RNF144B | c.615C>A p.G205= | Silent (SNP) | VAF 40/172 reads (23%) | catalogued as rs139497819; called by muse, mutect2, varscan2
- SCN3A | c.75C>A p.I25= | Silent (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- TTN | c.21732T>C p.Y7244= (on ENST00000591111; = p.Y6317= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/218 reads (33%) | catalogued as rs532700134; called by muse, mutect2, varscan2
- UBQLN2 | c.1470C>G p.G490= | Silent (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- UHRF1 | c.1599C>A p.V533= (on ENST00000612630 / NM_001290050.1; = p.V546= on NM_013282.4) | Silent (SNP) | VAF 59/324 reads (18%) | catalogued as rs781278514; called by muse, mutect2, varscan2
- WIPF3 | c.642G>C p.V214= | Silent (SNP) | VAF 10/37 reads (27%) | called by muse, varscan2
- ZNF653 | c.969G>A p.A323= | Silent (SNP) | VAF 34/164 reads (21%) | catalogued as COSV53403035; called by muse, mutect2, varscan2
- RASSF5 | c.579+19290G>T | Intron (SNP) | VAF 35/105 reads (33%) | catalogued as COSV58795475; called by muse, mutect2, varscan2
- RPL13A | c.402+83G>A | Intron (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- RPL13A | c.402+84A>T | Intron (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
